CPTAC case C3N-02971 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aec3c953-dd96-402f-807f-9be99d8a8aeb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Dead; Days to death: 70 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Iraq.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Tail of pancreas; Age at diagnosis: 78.4 years (28,635 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G1; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 70 days; Progression or recurrence: no; Days to last follow up: 70 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.6 cm (a second GDC size field records 3.2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 11; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 70 days; Disease response: With Tumor.

Other clinical attributes
- Weight: 69.4 kg; Height: 152.4 cm; BMI: 29.88; Diabetes treatment type: Insulin.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02971-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 9 days; Initial weight: 403 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02971-21: Section location: Tail; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-02971-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 9 days; Method of sample procurement: Blood Draw.
